Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-5403, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-5403-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

The patient is a [REDACTED]. A colonoscopy showed partially obstructing fungating tumor of the left colon close to splenic flexure. No other abnormalities seen. Bowel prep was suboptimal as a result of partial obstruction of poor bowel prep, evaluation was not continued. Biopsy of this lesion revealed adenocarcinoma.

PRE OP DIAGNOSIS: Colon cancer. TA

POST OP DIAGNOSIS: Same.

PROCEDURE: Not given.

ADDENDA:**Addendum**

At the request of [REDACTED], EGFR immunostaining was performed on a section of the colon cancer (slide 1H). The immunohistochemical stain for EGFR is negative, but this interpretation is based on an altered method (an original H&E stained slide from this case had to be de-stained in order to be stained for EGFR, a process that could potentially interfere with the immunohistochemical reaction). Thus, an additional EGFR stain has been requested on this patient's metastatic tumor [REDACTED] and is pending; the results will be reported as an addendum of [REDACTED].

FINAL DIAGNOSIS:**PART 1**

AND 2: LARGE INTESTINE, PARTIAL RESECTION WITH SUBSEQUENT REVISION OF "NEW PROXIMAL MARGIN" -

- A. INVASIVE MODERATELY DIFFERENTIATED COLONIC ADENOCARCINOMA EXTENDING THROUGH THE MUSCULARIS PROPRIA INTO THE SEROSAL ADIPOSE TISSUE. DIAMETER 6.5 CM. NO EVIDENCE OF ANGIOLYMPHATIC INVASION. PERINEURAL INVASION IDENTIFIED. ALL MARGINS FREE. PATHOLOGIC STAGE T3N0MX, DUKES' B, ASTLER COLLER B2.
- B. TWELVE (12) PERICOLONIC LYMPH NODES WITH NO EVIDENCE OF METASTATIC CARCINOMA.

[page 2 of 2]
MICROSCOPIC:

SYNOPTIC - PRIMARY COLON AND RECTAL TUMORS

- A. Location: 5
1. Ileocecal Region
2. Ascending Colon
3. Transverse Colon
4. Descending Colon
5. Sigmoid Colon
6. Rectum
- B. Procedure: 1
1. Segmental Colectomy
2. Total Colectomy
3. Other
- C. Size of Tumor (maximum dimension): 6.5 cm
- D. Type: 1
1. Adenocarcinoma, NOS
2. Adenocarcinoma arising in a background of an adenoma.
3. Adenocarcinoma arising in a background of inflammatory bowel disease
4. Adenosquamous carcinoma
5. Carcinoid Tumor (Neuroendocrine Tumor)
6. Mucinous Adenocarcinoma
7. Signet ring cell type Adenocarcinoma
8. Neuroendocrine Carcinoma
9. Squamous Cell Carcinoma
10. Undifferentiated Carcinoma
11. Sarcoma
12. Smooth Muscle Tumor
13. Gastrointestinal stromal tumor
14. Lymphoma
15. Other
- E. Grade: 2
1. Well differentiated
2. Moderately differentiated
3. Poorly differentiated
- F. Extent of Infiltration: 4
1. Limited to the mucosa
2. Into submucosa
3. Involving muscularis propria
4. Infiltrating through muscularis propria into serosal adipose tissue
5. Involving adjacent organs/ pelvic wall
- G. Angiolymphatic Invasion: 2
1. Yes
2. No
- H. Surgical Margins Involved: 2
1. Yes
2. No
- I. Regional Lymph Node Involvement: 2
1. Yes
2. No
- J. If regional lymph nodes involved, Number positive/number examined: N/A
- K. Extracapsular spread: N/A
1. Yes
2. No
- L. Associated conditions: N/A
1. Ulcerative colitis.
2. Crohns Disease.
3. History/ presence of adenomatous polyps.
4. Multiple polyposis syndromes.
5. Diverticulosis.
- M. TNM Stage: T 3 N 0 M x
- N. Dukes' Stage: 2
1. A (limited to mucosa and muscularis)
2. B (through muscularis into subserosa)
3. C (through subserosa and involving adjacent organ/pelvic wall/regional or distant lymph nodes)
- O. Astler - Coller Stage: 3
1. A (mucosa but not into muscularis propria)
2. B1 (muscularis propria but not through, LN negative)
3. B2 (through muscularis propria into subserosal fibroadipose tissue, LN negative)
4. C1 (limited to muscularis propria but not through serosa, LN positive)
5. C2 (invades serosal adipose tissue, LN positive)

Source: NCI Genomic Data Commons file 5961eceb-05f8-4dad-8586-329cd4be367e (TCGA-AZ-5403.AADE444B-F299-47CF-8837-E0DE4F044637.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).